Gene-level copy-number profile of tumor specimen TCGA-V5-A7RE-01A from TCGA case TCGA-V5-A7RE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 45.6 years (16,643 days).
Specimen TCGA-V5-A7RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.3d12c6c7-a81b-4918-8f7f-4fabaeafb176.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-A7RE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3157bea-2539-49ba-8892-3191192c626f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 1,239; copy number 2: 21,698; copy number 3: 28,136; copy number 4: 7,250; copy number 5: 791; copy number 6: 50; copy number 7: 243; copy number 8: 142; copy number 9: 73; copy number 10: 28; copy number 11: 8; copy number 12: 15; copy number 13: 74; copy number 15: 7; copy number 17: 1; copy number 18: 20; copy number 19: 5; copy number 20: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-A7RE-01A-11D-A350-01): tumor purity 0.64, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr10:16,207,821–17,129,811, 11 genes (within-gene range 0–2): RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2, CUBN.
- chr16:78,495,926–78,553,296, 4 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 622 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:11,643,404–12,818,291, 70 genes, copy number 7 (broad region; genes not listed).
- chr17:28,455,752–28,614,185, 1 gene, copy number 13 (within-gene range 2–13): AC005726.1.
- chr17:28,506,243–29,404,105, 63 genes, copy number 10–13 (broad region; genes not listed).
- chr17:29,390,662–29,390,730, 1 gene, copy number 10: MIR4523.
- chr17:39,461,486–39,864,312, 15 genes, copy number 18 (within-gene range 3–18): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:44,228,760–45,327,497, 62 genes, copy number 9 (broad region; genes not listed).
- chr17:50,962,174–51,171,744, 4 genes, copy number 10 (within-gene range 3–10): SPAG9, AC005920.2, NME1, NME1-NME2.
- chr17:51,761,260–51,763,397, 1 gene, copy number 17: AC002090.1.
- chr17:55,325,757–55,561,577, 6 genes, copy number 20: AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P.
- chr17:56,938,199–56,961,050, 1 gene, copy number 9 (within-gene range 2–9): COIL.
- chr17:56,951,664–57,255,855, 9 genes, copy number 9: AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2.
- chr17:57,277,920–57,280,017, 1 gene, copy number 9: AC091181.1.
- chr17:58,755,854–58,985,179, 1 gene, copy number 11 (within-gene range 4–11): PPM1E.
- chr17:58,835,899–60,422,470, 63 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:61,354,763–61,591,219, 9 genes, copy number 8: AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2.
- chr17:62,122,320–62,615,481, 15 genes, copy number 12 (within-gene range 4–12): Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3.
- chr17:62,841,101–63,864,379, 40 genes, copy number 8: PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2, MAP3K3, EEF1DP7, STRADA, LIMD2, AC046185.3, AC046185.1, CCDC47, DDX42, FTSJ3, PSMC5, SMARCD2, TCAM1P.
- chr17:66,302,613–66,810,743, 1 gene, copy number 15 (within-gene range 2–15): PRKCA.
- chr17:66,638,271–66,895,572, 6 genes, copy number 15: RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446.
- chr17:67,377,281–67,697,261, 1 gene, copy number 18 (within-gene range 4–18): PITPNC1.
- chr17:67,524,481–67,659,465, 4 genes, copy number 18: AC110921.1, AC079331.2, AC079331.1, AC079331.3.
- chr17:73,737,854–74,451,653, 19 genes, copy number 8–19: AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3, AC137735.2, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C.
- chr17:75,087,727–75,667,189, 33 genes, copy number 13 (within-gene range 3–13): SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6.
- chr18:47,390–5,630,700, 117 genes, copy number 7 (broad region; genes not listed).
- chr18:72,536,680–76,984,162, 78 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:77,002,849–77,006,846, 1 gene, copy number 8: AC093330.2.

Autosomal genes at a single copy (total copy number 1): 1,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
